Somatic mutation profile of tumor specimen TCGA-32-1976-01A (aliquot TCGA-32-1976-01A-01W-0837-08) from TCGA case TCGA-32-1976, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.2 years (23,798 days).
Specimen TCGA-32-1976-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc58eec8-f202-4627-ba98-eb6de9f4eaf3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-1976-10A (Blood Derived Normal), aliquot TCGA-32-1976-10A-01W-0838-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a489e954-de4b-4be5-8805-2e81fb3f2652

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 31, Silent 15, Frame Shift Del 3, Frame Shift Ins 3, In Frame Del 2, Splice Site 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.965); catalogued as rs112602953, CM075975, COSV56518008; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 68/194 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD33 | c.164G>A p.G55D (on ENST00000340970 / NM_001304459.2; = p.G190D on NM_182608.4) | Missense Mutation (SNP) | VAF 110/238 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs1361763298, COSV100001366, COSV56607360; called by muse, mutect2, varscan2
- ATP8A2 | c.2654A>G p.K885R | Missense Mutation (SNP) | VAF 92/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99682563; called by muse, mutect2, varscan2
- B3GNT4 | c.242_243del p.T81Sfs*3 | Frame Shift Del (DEL) | VAF 80/288 reads (28%) | catalogued as rs757016083; called by pindel, varscan2
- CALML5 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 135/208 reads (65%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs199855788, COSV100981195; called by muse, mutect2, varscan2
- CCR1 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99946733; called by muse, mutect2
- CD19 | c.1543C>T p.R515C (on ENST00000324662 / NM_001178098.2; = p.R514C on NM_001770.6) | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs561262269, COSV61187877, COSV61188443; called by muse, mutect2, varscan2
- CDKN3 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.713); catalogued as rs916278976, COSV99369894; called by muse, mutect2, varscan2
- CGB1 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs766888572, COSV56820127, COSV56820492; called by muse, mutect2, varscan2
- CNTN4 | c.2035G>A p.V679M | Missense Mutation (SNP) | VAF 366/995 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs1005802317, COSV100639391; called by muse, mutect2, varscan2
- CREBBP | c.4764G>C p.K1588N | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1450303039, COSV99270580; called by muse, mutect2, varscan2
- CYP4A22 | c.1111T>G p.Y371D | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99595049; called by muse, mutect2, varscan2
- ELOVL2 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.148); catalogued as rs1161557499, COSV61154120; called by muse, mutect2, varscan2
- FGFR4 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 204/606 reads (34%) | catalogued as rs762709356, COSV52812432; called by muse, mutect2, varscan2
- FSCB | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs764660753, COSV61219113; called by muse, mutect2, varscan2
- GEN1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV100438051; called by muse, mutect2, varscan2
- IFNA1 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 61/166 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.034); catalogued as COSV99439907; called by muse, varscan2
- ING3 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 78/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100187411; called by muse, varscan2
- JPH3 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767533433, COSV52465531; called by muse, mutect2, varscan2
- KIF12 | c.1924C>T p.R642W (on ENST00000640217; = p.R504W on NM_138424.1) | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs1043906838, COSV100936148, COSV100936184; called by muse, mutect2, varscan2
- LILRA4 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 188/539 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1484171073, COSV52490016; called by muse, mutect2, varscan2
- MBD6 | c.655_657del p.A219del | In Frame Del (DEL) | VAF 37/126 reads (29%) | catalogued as rs1211555693; called by mutect2, pindel, varscan2
- MMP8 | c.1127C>A p.A376E | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs752968761, COSV99368529; called by mutect2, varscan2
- MYH4 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99701530; called by muse, mutect2, varscan2
- NFAM1 | c.453C>T p.D151= | Splice Region (SNP) | VAF 28/90 reads (31%) | catalogued as rs765629601, COSV100215935; called by muse, mutect2
- OPN5 | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.143); catalogued as COSV99789880; called by muse, mutect2
- PCDH11Y | c.4014T>A p.H1338Q | Missense Mutation (SNP) | VAF 142/160 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV99291793; called by muse, mutect2, varscan2
- PIK3R1 | c.1748_1750del p.X583_splice (on ENST00000521381 / NM_181523.3; = p.X313_splice on NM_181504.4) | Splice Site (DEL) | VAF 66/209 reads (32%) | catalogued as rs1131692243; called by pindel, varscan2
- SALL4 | c.2983dup p.V995Gfs*16 | Frame Shift Ins (INS) | VAF 14/120 reads (12%) | catalogued as rs753320334; called by mutect2, varscan2
- SLC14A2 | c.2567G>T p.G856V | Missense Mutation (SNP) | VAF 22/738 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54914072, COSV99675663; called by muse, mutect2
- SLC15A3 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763376655, COSV99135634; called by muse, mutect2, varscan2
- SLC30A8 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 159/355 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs141202988, COSV69969422; called by muse, mutect2, varscan2
- SPDEF | c.60dup p.D21Rfs*44 | Frame Shift Ins (INS) | VAF 6/30 reads (20%) | catalogued as rs768568534; called by pindel, varscan2
- SULT1E1 | c.293T>A p.M98K | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV56947106; called by muse, mutect2, varscan2
- TANC1 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs183701876; called by muse, mutect2, varscan2
- TENM3 | c.7591G>A p.A2531T | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as rs753365136, COSV101305201; called by muse, mutect2, varscan2
- WNK3 | c.3577C>G p.Q1193E | Missense Mutation (SNP) | VAF 67/87 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV100671602; called by muse, mutect2, varscan2
- ABCB4 | c.85del p.Q29Kfs*9 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- CCNB1 | c.422del p.D141Afs*9 | Frame Shift Del (DEL) | VAF 93/288 reads (32%) | called by mutect2, pindel, varscan2
- PATZ1 | c.471dup p.Q158Tfs*142 | Frame Shift Ins (INS) | VAF 65/217 reads (30%) | called by mutect2, pindel, varscan2
- ZNF746 | c.878_880del p.E293del | In Frame Del (DEL) | VAF 30/146 reads (21%) | called by pindel, varscan2
- CABP1 | c.786C>T p.T262= (on ENST00000316803 / NM_001033677.1; = p.T59= on NM_004276.5) | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs564070934, COSV99974721; called by muse, mutect2, varscan2
- CCKAR | c.1155C>T p.F385= | Silent (SNP) | VAF 139/306 reads (45%) | catalogued as COSV99810348; called by muse, mutect2, varscan2
- CCN4 | c.504C>T p.P168= | Silent (SNP) | VAF 55/97 reads (57%) | catalogued as rs1463459190, COSV99137169; called by muse, mutect2, varscan2
- EMILIN2 | c.1431C>T p.G477= | Silent (SNP) | VAF 45/204 reads (22%) | catalogued as rs748210111, COSV54425830; called by muse, mutect2, varscan2
- FUT1 | c.195C>T p.N65= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs763594230, COSV55810775; called by muse, mutect2, varscan2
- GRM4 | c.69C>T p.Y23= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs576147584, COSV100946391; called by muse, mutect2, varscan2
- ING3 | c.63C>A p.R21= | Silent (SNP) | VAF 77/389 reads (20%) | catalogued as rs932370241, COSV100187412; called by muse, varscan2
- LRRC7 | c.1011T>A p.S337= (on ENST00000651989 / NM_001370785.2; = p.S304= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV99227747; called by muse, mutect2, varscan2
- MFSD10 | c.1014C>T p.A338= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs760895271, COSV99296621; called by muse, mutect2
- NLRP4 | c.852G>A p.P284= | Silent (SNP) | VAF 71/126 reads (56%) | catalogued as rs200215054, COSV56710779; called by muse, mutect2, varscan2
- NPC1L1 | c.1044G>T p.V348= | Silent (SNP) | VAF 51/166 reads (31%) | catalogued as rs747696584, COSV99212413; called by muse, mutect2, varscan2
- OR2A1 | c.300C>A p.T100= | Silent (SNP) | VAF 104/1339 reads (8%) | catalogued as COSV101283400; called by muse, mutect2
- OR8S1 | c.72G>T p.R24= | Silent (SNP) | VAF 188/373 reads (50%) | catalogued as COSV100043604; called by muse, mutect2, varscan2
- OR8U1 | c.516C>T p.N172= | Silent (SNP) | VAF 186/920 reads (20%) | catalogued as rs1389311151, COSV100163979; called by muse, varscan2
- STK19 | c.99G>A p.E33= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs763903930, COSV100514730; called by muse, mutect2, varscan2
